Somatic mutation profile of tumor specimen TCGA-29-1694-01A (aliquot TCGA-29-1694-01A-01W-0633-09) from TCGA case TCGA-29-1694, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 45.2 years (16,523 days).
Specimen TCGA-29-1694-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf3f7ead-76ce-49d3-ba6a-5c2757193912.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1694-10A (Blood Derived Normal), aliquot TCGA-29-1694-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64801f7d-3204-4b3c-8179-ca9305c98b8c

The open-access MAF lists 41 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 3, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-8_799del p.X261_splice | Splice Site (DEL) | VAF 16/25 reads (64%) | hotspot (GDC flag); called by mutect2, pindel
- ALMS1 | c.5003G>A p.R1668K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.205); catalogued as COSV52506651; called by muse, mutect2, varscan2
- CCDC146 | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV53546176; called by muse, mutect2, varscan2
- CDK13 | c.3235+1G>C p.X1079_splice | Splice Site (SNP) | VAF 11/20 reads (55%) | catalogued as COSV51697947; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3901C>T p.Q1301* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as rs375727174; called by muse, mutect2, varscan2
- CHD7 | c.4142G>T p.C1381F | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV71108487; called by muse, mutect2, varscan2
- CHEK2 | c.1672-1G>T p.X558_splice (on ENST00000382580 / NM_001005735.2; = p.X515_splice on NM_007194.4) | Splice Site (SNP) | VAF 9/11 reads (82%) | catalogued as COSV60418258; called by muse, mutect2, varscan2
- COL13A1 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100637523; called by muse, mutect2
- GABRG2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62715377, COSV62715450; called by muse, mutect2
- HERC6 | c.2011A>T p.R671* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99986760; called by muse, mutect2
- HTR7 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53284770; called by muse, mutect2, varscan2
- KDM5A | c.1963C>G p.Q655E | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV66991459; called by muse, mutect2, varscan2
- KIF13B | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV73054208; called by muse, mutect2, varscan2
- LCE2A | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV64226739; called by muse, mutect2, varscan2
- MYH2 | c.5813T>A p.I1938K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55434733; called by muse, mutect2, varscan2
- NTNG1 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV53990970; called by muse, mutect2
- OR13C8 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV58610793; called by muse, mutect2, varscan2
- PAK5 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775109543, COSV62024484, COSV62026588; called by muse, mutect2, varscan2
- PARP14 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV71734334; called by muse, mutect2, varscan2
- PCSK7 | c.1434C>G p.I478M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs750606551, COSV100309415; called by muse, mutect2
- PLA2G2C | c.262A>C p.I88L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV56124258; called by muse, mutect2, varscan2
- SLC38A5 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV58333780; called by muse, mutect2, varscan2
- TG | c.8235G>T p.L2745F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV55070765; called by muse, mutect2, varscan2
- THBS4 | c.842C>A p.A281E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.105); catalogued as COSV63468685; called by muse, mutect2, varscan2
- TMEM132D | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs1414407354, COSV67159575; called by muse, mutect2, varscan2
- TTN | c.46256C>A p.T15419N (on ENST00000591111; = p.T7995N on NM_003319.4) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | PolyPhen probably damaging (0.997); catalogued as COSV59928369, COSV59964398; called by muse, mutect2, varscan2
- VAV3 | c.1940T>A p.V647D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.311); catalogued as COSV58379855; called by muse, mutect2, varscan2
- ZIK1 | c.861A>T p.R287S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56736792; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2028_2029del p.G678Kfs*10 | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | called by mutect2, pindel, varscan2
- NF1 | c.3476_3488del p.S1159Tfs*3 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- OR4C6 | c.884_891del p.A295Efs*? | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | called by mutect2, pindel, varscan2
- RYR3 | c.3051_3062del p.R1018_P1021del | In Frame Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- AKAP9 | c.2967A>G p.Q989= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100661883, COSV62342304; called by muse, mutect2, varscan2
- ANOS1 | c.1317C>A p.G439= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV52917695; called by muse, mutect2, varscan2
- DNAH9 | c.9852C>A p.P3284= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV52342913; called by muse, mutect2, varscan2
- METTL24 | c.666C>T p.H222= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as rs747456793, COSV58821546; called by muse, mutect2, varscan2
- OR51B5 | c.657A>T p.I219= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV56175439; called by muse, mutect2, varscan2
- TAF1L | c.1806C>A p.T602= | Silent (SNP) | VAF 57/95 reads (60%) | catalogued as COSV54259956, COSV54265989; called by muse, mutect2, varscan2
- TMEM183A | c.600G>A p.R200= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100923854; called by muse, mutect2
- TRIM67 | c.1369T>C p.L457= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV64158508; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80558899 G>A | 5'Flank (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
